Somatic mutation profile of tumor specimen MMRF_1049_1_BM_CD138pos (aliquot MMRF_1049_1_BM_CD138pos_T1_KHS5U_K14066) from MMRF case MMRF_1049, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.0 years (24,843 days).
Specimen MMRF_1049_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3adf8ed7-4fdd-4ba6-b130-c4f762d1f3f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1049_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1049_1_PB_Whole_C2_KHS5U_K14065; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef09c281-8216-46f6-9288-e3b117a42170

The open-access MAF lists 117 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 25, Intron 19, Silent 12, 5'UTR 9, RNA 5, Nonsense Mutation 4, 5'Flank 4, Translation Start Site 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1355815263, COSV51402328; called by muse, mutect2, varscan2
- BMP4 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs1258588645; called by muse, mutect2, varscan2
- CDK2AP1 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as rs762855598; called by muse, mutect2
- EGR1 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs199695186; called by muse, mutect2, varscan2
- ELAVL4 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs200396874, COSV100836643; called by muse, mutect2, varscan2
- GABRA5 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 166/276 reads (60%) | catalogued as COSV59475659; called by muse, mutect2, varscan2
- GJD2 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51747204; called by muse, mutect2, varscan2
- HKDC1 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100664333; called by muse, mutect2, varscan2
- IGHV2-70 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs779974345; called by mutect2, varscan2
- IGHV4-34 | c.326G>C p.S109T | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs765275600; called by muse, mutect2, varscan2
- IGKV4-1 | c.215T>A p.L72Q | Missense Mutation (SNP) | VAF 78/78 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as rs368410084; called by muse, mutect2, varscan2
- IGSF9 | c.2296G>A p.A766T (on ENST00000368094 / NM_001135050.2; = p.A750T on NM_020789.4) | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.177); catalogued as rs906876689; called by muse, mutect2, varscan2
- IRS4 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 47/51 reads (92%) | catalogued as COSV100929429; called by muse, mutect2, varscan2
- KCTD17 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.039); catalogued as rs1261369510; called by muse, mutect2, varscan2
- KLRF1 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV54380568; called by muse, mutect2
- MISP | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 92/187 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV53119921; called by muse, mutect2, varscan2
- OR4D5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 70/108 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs141977995, COSV100189634; called by muse, mutect2, varscan2
- PCDHGA3 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53951173; called by muse, mutect2, varscan2
- SYNGAP1 | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs574603811; called by muse, mutect2, varscan2
- TSPOAP1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs765140985, COSV52109382; called by muse, mutect2, varscan2
- ZNF223 | c.233C>A p.S78* | Nonsense Mutation (SNP) | VAF 51/284 reads (18%) | catalogued as COSV71571828; called by muse, mutect2, varscan2
- AFTPH | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 82/372 reads (22%) | called by muse, mutect2, varscan2
- AP4B1 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CNGA2 | c.1514A>G p.D505G | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CWH43 | c.449A>T p.Q150L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HDHD2 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IGBP1P2 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGHV2-70 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.352); called by mutect2, varscan2
- IGHV2-70D | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 38/39 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRAG1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); called by muse, varscan2
- MNT | c.223G>C p.A75P | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- OR2T29 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 90/352 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR2T5 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- PCDH15 | c.4289C>A p.A1430E | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- PRDM9 | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- PRMT8 | c.557G>C p.W186S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB3A | c.609G>C p.Q203H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- RASGRF2 | c.2165G>A p.C722Y | Missense Mutation (SNP) | VAF 78/325 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- SUPT5H | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TENT5C | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TGM1 | c.509-2A>T p.X170_splice | Splice Site (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- TMEM26 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ABCA1 | c.6765A>G p.K2255= | Silent (SNP) | VAF 58/354 reads (16%) | called by muse, mutect2, varscan2
- ABCA7 | c.4875G>C p.L1625= | Silent (SNP) | VAF 37/130 reads (28%) | catalogued as rs754027385; called by muse, mutect2, varscan2
- ADAMTS5 | c.984G>A p.L328= | Silent (SNP) | VAF 44/273 reads (16%) | catalogued as rs760808495; called by muse, mutect2, varscan2
- BTBD1 | c.966A>G p.R322= | Silent (SNP) | VAF 58/285 reads (20%) | called by muse, mutect2, varscan2
- FOXD3 | c.1179C>T p.G393= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs929422083; called by muse, mutect2, varscan2
- IGHV1-69 | c.105C>G p.S35= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs782604358; called by mutect2, varscan2
- IGHV2-70D | c.358C>G p.*120= | Silent (SNP) | VAF 16/17 reads (94%) | called by muse, mutect2, varscan2
- IGHV3-33 | c.69G>C p.L23= | Silent (SNP) | VAF 29/65 reads (45%) | called by muse, varscan2
- LTB4R2 | c.283C>T p.L95= (on ENST00000528054; = p.L64= on NM_019839.5) | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- PIWIL4 | c.2247C>T p.N749= | Silent (SNP) | VAF 47/189 reads (25%) | catalogued as rs756931190; called by muse, mutect2, varscan2
- TNS3 | c.2787C>A p.T929= | Silent (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.408C>T p.R136= | Silent (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- AC020765.6 | c.-42G>A | 5'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- ADH5P5 | chr5:23980142 T>C | 5'Flank (SNP) | VAF 23/122 reads (19%) | called by muse, mutect2
- ANKH | c.*4608C>T | 3'UTR (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- ATP6V0E2 | chr7:149873497 G>T | 5'Flank (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.950G>T | RNA (SNP) | VAF 113/644 reads (18%) | called by muse, mutect2, varscan2
- C9orf57 | c.*2T>C | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by mutect2, varscan2
- CCN2 | c.*785T>C | 3'UTR (SNP) | VAF 27/98 reads (28%) | catalogued as rs867008423; called by muse, mutect2, varscan2
- CCND2 | c.*1358A>T | 3'UTR (SNP) | VAF 6/40 reads (15%) | catalogued as rs1286939073, COSV54224367; called by muse, varscan2
- CDH6 | c.*637A>G | 3'UTR (SNP) | VAF 11/141 reads (8%) | called by muse, mutect2
- DEFB134 | chr8:11993557 A>T | 3'Flank (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- DLX6 | c.-246C>G | 5'UTR (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- EYS | c.862+45A>T | Intron (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- FAM171A1 | c.*814G>A | 3'UTR (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- FAM217B | c.*1232T>A | 3'UTR (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- FASTKD2 | c.2013+14G>A | Intron (SNP) | VAF 29/131 reads (22%) | catalogued as COSV52700286; called by muse, mutect2, varscan2
- FASTKD2 | c.2013+15C>T | Intron (SNP) | VAF 30/131 reads (23%) | called by muse, mutect2, varscan2
- FLCN | c.-24-703_-24-693del | Intron (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- FOXK2 | c.*322G>T | 3'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137035862 G>A | 5'Flank (SNP) | VAF 31/114 reads (27%) | called by muse, mutect2, varscan2
- GOLGA7B | c.*1762T>C | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- GRIN1 | c.2589+66C>T | Intron (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- IBA57 | c.*493G>A | 3'UTR (SNP) | VAF 54/122 reads (44%) | catalogued as rs941484757; called by muse, mutect2, varscan2
- INTS11 | c.429+196C>T | Intron (SNP) | VAF 53/116 reads (46%) | catalogued as rs755105272; called by muse, mutect2, varscan2
- ITGA9 | c.2154+54C>A | Intron (SNP) | VAF 36/131 reads (27%) | called by muse, mutect2
- KIF1A | c.*3162C>A | 3'UTR (SNP) | VAF 46/118 reads (39%) | called by muse, mutect2, varscan2
- KIFC3 | c.172+79C>T | Intron (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- KLRF1 | c.-50T>C | 5'UTR (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- KMT5B | c.*1329A>T | 3'UTR (SNP) | VAF 58/82 reads (71%) | called by muse, mutect2, varscan2
- KRIT1 | c.486-78_486-77del | Intron (DEL) | VAF 66/162 reads (41%) | called by pindel, varscan2
- LINC02692 | n.828G>T | RNA (SNP) | VAF 48/74 reads (65%) | called by muse, mutect2, varscan2
- LMO7 | c.1026-23A>C | Intron (SNP) | VAF 38/69 reads (55%) | called by muse, mutect2, varscan2
- LTBP1 | c.-179T>G | 5'UTR (SNP) | VAF 95/150 reads (63%) | called by muse, mutect2, varscan2
- LYSMD2 | c.*131C>T | 3'UTR (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- MAGI2 | c.-3G>A | 5'UTR (SNP) | VAF 72/127 reads (57%) | catalogued as rs759941427; called by muse, mutect2, varscan2
- MMS22L | c.607-321G>A | Intron (SNP) | VAF 14/43 reads (33%) | catalogued as rs536379694; called by muse, mutect2, varscan2
- MRGPRX10P | n.245C>T | RNA (SNP) | VAF 41/97 reads (42%) | catalogued as rs1007764171; called by muse, mutect2, varscan2
- MRGPRX10P | n.75A>G | RNA (SNP) | VAF 36/154 reads (23%) | called by muse, mutect2, varscan2
- MYRIP | c.-21C>T | 5'UTR (SNP) | VAF 54/266 reads (20%) | called by muse, mutect2, varscan2
- NNAT | chr20:37521224 T>A | 5'Flank (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- NUDT4 | c.*8387T>A | 3'UTR (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- NUP160 | c.*981T>G | 3'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, varscan2
- NUP160 | c.*922T>G | 3'UTR (SNP) | VAF 30/83 reads (36%) | called by muse, varscan2
- OCM2 | c.-60T>A | 5'UTR (SNP) | VAF 120/412 reads (29%) | called by muse, mutect2, varscan2
- OR5M4P | n.433T>A | RNA (SNP) | VAF 68/103 reads (66%) | called by muse, mutect2, varscan2
- PDE10A | c.2268-150C>G | Intron (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- PDE8A | c.*1185A>T | 3'UTR (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- PDGFRB | c.*676C>T | 3'UTR (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- PDLIM3 | c.94-67C>T | Intron (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- PTGER2 | c.*389C>A | 3'UTR (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- RINL | c.1342+83G>C | Intron (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2, varscan2
- RND1 | c.*586T>G | 3'UTR (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- RRP15 | c.*5095C>T | 3'UTR (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- SEC16B | c.999-84T>C | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- SH2B3 | c.*635C>T | 3'UTR (SNP) | VAF 45/100 reads (45%) | called by muse, mutect2, varscan2
- SLC38A10 | c.-243G>A | 5'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- SNX13 | c.441-6613_441-6612del | Intron (DEL) | VAF 40/126 reads (32%) | catalogued as rs1376814459; called by mutect2, pindel, varscan2
- SP8 | c.-233A>G | 5'UTR (SNP) | VAF 94/287 reads (33%) | called by muse, mutect2, varscan2
- SSBP3 | c.*410C>T | 3'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- TMEM170A | c.*4274A>G | 3'UTR (SNP) | VAF 28/32 reads (88%) | called by muse, mutect2, varscan2
- TSPEAR | c.1566+2127G>A | Intron (SNP) | VAF 50/227 reads (22%) | catalogued as rs906476505; called by muse, mutect2, varscan2
- TTLL5 | c.740+1680G>A | Intron (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- WNT2B | c.*497C>T | 3'UTR (SNP) | VAF 21/57 reads (37%) | catalogued as rs918441591; called by muse, mutect2, varscan2
- ZIC4 | c.*-147G>T | Intron (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
